Somatic mutation profile of tumor specimen TCGA-63-A5MN-01A (aliquot TCGA-63-A5MN-01A-22D-A27K-08) from TCGA case TCGA-63-A5MN, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42f2938a-824f-4ef2-931f-eb6187823246.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MN-10A (Blood Derived Normal), aliquot TCGA-63-A5MN-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a782b898-2fb2-4705-a8a4-dd3ad5268db8

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 23, Silent 10, Frame Shift Ins 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP4 | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as COSV99567559; called by muse, mutect2
- ADGRB2 | c.4369G>A p.G1457S | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs1310354410, COSV57079182, COSV99925741; called by muse, mutect2
- ANO3 | c.2813T>G p.V938G | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV56779648, COSV99880698; called by muse, mutect2
- ASXL3 | c.3277G>A p.G1093S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); catalogued as COSV99323504; called by muse, mutect2, varscan2
- BRINP3 | c.814A>T p.I272F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100818377; called by muse, mutect2, varscan2
- BRWD3 | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1368496222, COSV64751478; called by muse, mutect2, varscan2
- CCDC73 | c.2925C>A p.D975E | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100066501; called by muse, mutect2
- CENPT | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV99534853; called by muse, mutect2
- CNGA1 | c.1345G>T p.V449F | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs748380011, COSV100652126; called by muse, mutect2
- GNPTAB | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV100171696; called by muse, mutect2
- KIAA1210 | c.3220A>T p.S1074C | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV101273924; called by muse, mutect2, varscan2
- MPPED2 | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100813104; called by muse, mutect2
- NR4A1 | c.1446G>C p.W482C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54481188, COSV99671015; called by muse, mutect2, varscan2
- OR4C12 | c.453T>G p.F151L | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.107); catalogued as COSV100078278, COSV58861519; called by muse, mutect2
- ORM1 | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs1467195873, COSV99407434; called by muse, mutect2, varscan2
- POT1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62930052; called by muse, mutect2, varscan2
- RIMKLB | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.518); catalogued as COSV100223746; called by muse, mutect2
- RPL10 | c.43A>C p.K15Q | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV99185816; called by muse, mutect2, varscan2
- SETD6 | c.817C>T p.Q273* (on ENST00000219315 / NM_001160305.4; = p.Q249* on NM_024860.3) | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99261721; called by muse, mutect2, varscan2
- SH3PXD2A | c.2387A>G p.K796R (on ENST00000369774 / NM_001365079.1; = p.K768R on NM_014631.2) | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100279867; called by muse, mutect2, varscan2
- SNRPA1 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54258618; called by muse, mutect2
- SPTAN1 | c.6982T>A p.F2328I | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100823258; called by muse, mutect2
- TIAM2 | c.2820G>T p.E940D | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100018015; called by muse, mutect2, varscan2
- ZDHHC3 | c.650T>G p.L217R (on ENST00000424952 / NM_001135179.2; = p.L245R on NM_016598.3) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99943311; called by mutect2, varscan2
- ZMYM3 | c.3654G>C p.K1218N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100077460; called by muse, mutect2
- LRRK1 | c.3913dup p.R1305Pfs*82 | Frame Shift Ins (INS) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- ZNF618 | c.1817dup p.V607Rfs*100 (on ENST00000374126 / NM_001318042.2; = p.V514Rfs*100 on NM_133374.2) | Frame Shift Ins (INS) | VAF 13/126 reads (10%) | called by mutect2, pindel, varscan2
- EPPK1 | c.3645C>A p.T1215= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV101599736; called by muse, mutect2
- GAD2 | c.270G>A p.A90= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV52149852; called by muse, mutect2
- KRTAP10-9 | c.558C>G p.V186= | Silent (SNP) | VAF 60/521 reads (12%) | catalogued as COSV100551974; called by muse, mutect2, varscan2
- PCDHB10 | c.1608C>T p.R536= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs782558627, COSV99503691; called by muse, mutect2, varscan2
- PKMYT1 | c.570C>T p.C190= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs762153541, COSV99233859; called by muse, mutect2, varscan2
- POLN | c.1470C>T p.G490= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV101242477; called by muse, mutect2, varscan2
- PRDM9 | c.1701C>G p.L567= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as COSV57005729, COSV99689812; called by muse, mutect2
- PYROXD2 | c.1569C>T p.C523= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as rs552656159, COSV65331319; called by muse, mutect2, varscan2
- RAB3C | c.321T>A p.I107= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV99276742; called by muse, mutect2, varscan2
- SLCO3A1 | c.876C>T p.H292= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs772405960, COSV100574930; called by muse, mutect2
